Somatic mutation profile of cancer-model specimen HCM-CSHL-0861-C25-85M (3D Organoid, passage 8; aliquot HCM-CSHL-0861-C25-85M-01D-A85L-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0861-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 65.8 years (24,023 days).
Specimen HCM-CSHL-0861-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c84931f4-e3f1-403e-ba23-f3a513d27d2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0861-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0861-C25-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/278bafe3-f5fb-4a17-bbcd-81fba864262a

The open-access MAF lists 74 somatic variants for this specimen: 49 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 22, Intron 3, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 130/312 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.794T>G p.L265R | Missense Mutation (SNP) | VAF 170/170 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD004355, CM971505, COSV52706540, COSV52732531, COSV53696163; called by muse, mutect2, varscan2
- ACSF3 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 23/359 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.738); catalogued as rs373794208, COSV58077600; called by muse, mutect2
- ANK2 | c.11182G>A p.V3728I | Missense Mutation (SNP) | VAF 216/327 reads (66%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs773907372; called by muse, mutect2, varscan2
- BMP10 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 222/379 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145545108; called by muse, mutect2, varscan2
- CHST3 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 104/480 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as rs1421686530; called by muse, mutect2, varscan2
- COG2 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 152/353 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV64187359; called by muse, mutect2, varscan2
- CPAMD8 | c.614C>T p.P205L (on ENST00000651564; = p.P158L on NM_015692.5) | Missense Mutation (SNP) | VAF 221/323 reads (68%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV52240125; called by muse, mutect2, varscan2
- CYB5D2 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 187/187 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.131); catalogued as rs758750553; called by muse, varscan2
- DLGAP2 | c.2326G>A p.A776T | Missense Mutation (SNP) | VAF 244/245 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); catalogued as rs1283667939, COSV70093658, COSV70101986; called by muse, mutect2, varscan2
- EDEM3 | c.1873G>A p.G625R | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58925566; called by muse, mutect2
- FRMD4A | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 118/274 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as rs763391755; called by muse, mutect2, varscan2
- FSCN3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 45/562 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as rs551537439, COSV50001406; called by muse, mutect2
- LCP1 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 222/683 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs1184846139, COSV59941551, COSV59942132; called by muse, mutect2, varscan2
- MME | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201459271; called by muse, mutect2, varscan2
- PLEKHG4B | c.1460C>T p.P487L (on ENST00000283426; = p.P843L on NM_052909.5) | Missense Mutation (SNP) | VAF 182/334 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0.107); catalogued as rs149715797; called by muse, mutect2, varscan2
- PON2 | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 108/220 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56002519; called by muse, mutect2, varscan2
- SETBP1 | c.4144del p.A1382Lfs*14 | Frame Shift Del (DEL) | VAF 169/237 reads (71%) | catalogued as COSV56324069; called by mutect2, pindel, varscan2
- SLCO1C1 | c.365G>C p.G122A | Missense Mutation (SNP) | VAF 138/322 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99859753; called by muse, mutect2, varscan2
- SOX5 | c.1564A>T p.M522L | Missense Mutation (SNP) | VAF 164/326 reads (50%) | SIFT tolerated (0.85); PolyPhen benign (0.046); catalogued as COSV58625638; called by muse, mutect2, varscan2
- SPATC1 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 232/716 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs782820649; called by mutect2, varscan2
- SZT2 | c.4090A>G p.S1364G (on ENST00000634258 / NM_001365999.1; = p.S1307G on NM_015284.4) | Missense Mutation (SNP) | VAF 163/345 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV65171128; called by muse, mutect2, varscan2
- TAF6L | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 204/430 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs1300765424; called by muse, mutect2, varscan2
- TMEM151B | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 43/646 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1385595151, COSV65255419; called by muse, mutect2
- UNC45B | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 15/431 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV52096717; called by muse, mutect2
- ADNP2 | c.2885T>G p.L962R | Missense Mutation (SNP) | VAF 165/345 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ASCC3 | c.4695A>C p.R1565S | Missense Mutation (SNP) | VAF 161/319 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC6 | c.730T>C p.S244P | Missense Mutation (SNP) | VAF 16/373 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- CLCC1 | c.116T>A p.M39K | Missense Mutation (SNP) | VAF 93/181 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DENND5B | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 201/424 reads (47%) | called by muse, mutect2, varscan2
- DHRS13 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 201/377 reads (53%) | called by muse, mutect2, varscan2
- DNAH9 | c.2365T>G p.Y789D | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- DQX1 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 189/462 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- FPGS | c.514_522del p.V172_M174del | In Frame Del (DEL) | VAF 155/370 reads (42%) | called by mutect2, pindel, varscan2
- FRMD4A | c.834C>T p.R278= | Splice Region (SNP) | VAF 117/275 reads (43%) | called by muse, mutect2, varscan2
- LDB1 | c.353-1_353dup p.I119Pfs*6 (on ENST00000425280 / NM_001321612.2; = p.I83Pfs*6 on NM_003893.5) | Frame Shift Ins (INS) | VAF 93/245 reads (38%) | called by mutect2, pindel, varscan2
- MED6 | c.694_697del p.T232* | Frame Shift Del (DEL) | VAF 54/310 reads (17%) | called by pindel, varscan2
- MUC17 | c.2995G>T p.E999* | Nonsense Mutation (SNP) | VAF 252/556 reads (45%) | called by muse, mutect2, varscan2
- NARF | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 142/142 reads (100%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.718); called by muse, varscan2
- PALM3 | c.559T>C p.C187R (on ENST00000340790; = p.C202R on NM_001145028.2) | Missense Mutation (SNP) | VAF 43/450 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- PPP2R5B | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTP5 | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 35/683 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2
- SLC22A15 | c.1009T>C p.Y337H | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.434); called by muse, mutect2
- SLC6A4 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- SPATA31D1 | c.4454A>G p.Y1485C | Missense Mutation (SNP) | VAF 22/397 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- TMEM245 | c.2263A>G p.T755A | Missense Mutation (SNP) | VAF 209/400 reads (52%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- TRANK1 | c.7874G>T p.R2625I | Missense Mutation (SNP) | VAF 20/488 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2
- UBTF | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF287 | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 228/228 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ACAP3 | c.186C>T p.R62= | Silent (SNP) | VAF 37/347 reads (11%) | catalogued as rs752582607; called by muse, mutect2, varscan2
- ALPK2 | c.3231C>T p.P1077= | Silent (SNP) | VAF 172/172 reads (100%) | called by muse, mutect2, varscan2
- CSF1R | c.2139T>C p.S713= | Silent (SNP) | VAF 149/149 reads (100%) | called by muse, mutect2, varscan2
- CUBN | c.5607T>A p.P1869= | Silent (SNP) | VAF 14/434 reads (3%) | called by muse, mutect2
- GLYR1 | c.111C>T p.R37= | Silent (SNP) | VAF 58/423 reads (14%) | catalogued as rs534080949; called by muse, mutect2, varscan2
- H2BC12 | c.126G>C p.V42= | Silent (SNP) | VAF 218/492 reads (44%) | catalogued as rs566842066; called by muse, mutect2, varscan2
- IVL | c.165C>A p.V55= | Silent (SNP) | VAF 86/358 reads (24%) | called by muse, mutect2, varscan2
- LTBP2 | c.2232C>T p.A744= | Silent (SNP) | VAF 303/626 reads (48%) | catalogued as rs150924217; called by muse, mutect2, varscan2
- MAGI2 | c.3312G>A p.G1104= | Silent (SNP) | VAF 23/669 reads (3%) | called by muse, mutect2
- MARCHF4 | c.807A>G p.Q269= | Silent (SNP) | VAF 86/334 reads (26%) | catalogued as COSV56103620; called by muse, mutect2, varscan2
- NPR1 | c.2382C>T p.F794= | Silent (SNP) | VAF 155/328 reads (47%) | called by muse, mutect2, varscan2
- NTRK3 | c.1827T>C p.D609= | Silent (SNP) | VAF 26/393 reads (7%) | catalogued as rs1303839085; called by muse, mutect2
- OR5L1 | c.189C>T p.L63= | Silent (SNP) | VAF 267/531 reads (50%) | catalogued as rs1272160448, COSV61735431; called by muse, mutect2, varscan2
- PCLO | c.7389G>A p.E2463= | Silent (SNP) | VAF 216/368 reads (59%) | catalogued as rs779070358; called by muse, mutect2, varscan2
- PDZRN3 | c.261C>T p.R87= | Silent (SNP) | VAF 275/531 reads (52%) | called by muse, mutect2, varscan2
- PHF12 | c.3006T>G p.S1002= | Silent (SNP) | VAF 164/330 reads (50%) | called by muse, mutect2, varscan2
- PLEKHA8 | c.912C>G p.G304= | Silent (SNP) | VAF 120/306 reads (39%) | called by muse, mutect2, varscan2
- RIMS2 | c.1512C>T p.G504= (on ENST00000666250 / NM_001348490.2; = p.G312= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 182/526 reads (35%) | catalogued as rs758569920, COSV51656297; called by muse, varscan2
- SORCS3 | c.2607C>T p.Y869= | Silent (SNP) | VAF 90/446 reads (20%) | catalogued as rs527874475, COSV63794676; called by muse, mutect2, varscan2
- TDRD3 | c.1674T>C p.P558= | Silent (SNP) | VAF 244/374 reads (65%) | called by muse, mutect2, varscan2
- TRIB3 | c.825C>T p.R275= | Silent (SNP) | VAF 41/298 reads (14%) | catalogued as rs371966597; called by muse, mutect2, varscan2
- ZCRB1 | c.36G>A p.V12= | Silent (SNP) | VAF 26/528 reads (5%) | called by muse, mutect2
- RGS3 | c.415+1645C>G | Intron (SNP) | VAF 182/398 reads (46%) | called by muse, mutect2, varscan2
- TTN | c.34522+1067C>A | Intron (SNP) | VAF 9/22 reads (41%) | called by mutect2, varscan2
- ZNF783 | c.802+3191G>A | Intron (SNP) | VAF 306/637 reads (48%) | catalogued as rs756395745, COSV65185521; called by muse, mutect2, varscan2
